Gene-level copy-number profile of tumor specimen TCGA-D9-A6E9-06A from TCGA case TCGA-D9-A6E9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.4 years (27,537 days).
Specimen TCGA-D9-A6E9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.d12428ef-4a82-44d2-9c42-a153cc7b636d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D9-A6E9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2fdceb90-0287-48a3-bb42-9f3af549ec4a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 35; copy number 2: 11,754; copy number 3: 19,973; copy number 4: 7,191; copy number 5: 15,513; copy number 6: 3,857; copy number 7: 1,399; copy number 8: 2; copy number 10: 34; copy number 25: 26; copy number 30: 11; copy number 32: 4; copy number 35: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D9-A6E9-06A-12D-A30W-01): tumor purity 0.37, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,522,666–181,523,001, 1 gene: AC093840.1.
- chr10:87,591,607–87,845,612, 8 genes: AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,488 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:205,042,937–205,285,632, 9 genes, copy number 7: CNTN2, TMEM81, RBBP5, AL583832.1, AC093422.2, DSTYK, AC093422.1, TMCC2, TMCC2-AS1.
- chr3:68,975,217–69,056,622, 3 genes, copy number 32 (within-gene range 2–32): EOGT, AC109587.1, TMF1.
- chr3:69,168,782–70,518,064, 11 genes, copy number 30 (within-gene range 2–30): FRMD4B, RBM43P1, AC099328.1, AC099328.2, AC104445.1, MITF, RN7SL418P, SAMMSON, AC139700.1, UQCRHP4, MDFIC2.
- chr5:114,475,339–114,668,410, 2 genes, copy number 8: AC010230.1, LINC01957.
- chr6:24,750,671–26,001,775, 40 genes, copy number 7: AL133264.1, GMNN, ARMH2, AL512428.1, RIPOR2, MTCO2P33, PPIAP29, AL160400.1, ASS1P1, RN7SL334P, AL133268.3, AL133268.2, CMAHP, AL133268.4, AL133268.1, AL590084.3, AL590084.1, AL590084.2, KATNBL1P5, AL024509.2, AL024509.1, CARMIL1, Y_RNA, RNU6-987P, AL022170.1, SCGN, PRELID1P2, H2AC1, H2BC1, H2BC2P, H2AC2P, SLC17A4, SLC17A1, SLC17A3, H2AC3P, H2BP5, SLC17A2, TRIM38, U91328.2, U91328.1.
- chr6:28,410,270–29,708,547, 75 genes, copy number 7 (broad region; genes not listed).
- chr6:31,863,192–32,407,763, 46 genes, copy number 7 (within-gene range 4–7): SLC44A4, EHMT2-AS1, EHMT2, C2, ZBTB12, AL645922.1, C2-AS1, CFB, NELFE, MIR1236, SKIV2L, DXO, STK19, C4A, C4A-AS1, CYP21A1P, TNXA, STK19B, C4B, C4B-AS1, CYP21A2, TNXB, RNA5SP206, AL662884.2, AL662884.5, ATF6B, FKBPL, PRRT1, AL662884.4, AL662884.3, PPT2, PPT2-EGFL8, EGFL8, AGPAT1, MIR6721, RNF5, MIR6833, AGER, AL662884.1, PBX2, GPSM3, NOTCH4, TSBP1-AS1, TSBP1, HNRNPA1P2, RNU6-603P.
- chr6:35,943,516–58,438,364, 450 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr12:42,456,757–42,590,355, 1 gene, copy number 35 (within-gene range 4–35): PRICKLE1.
- chr12:42,615,221–43,163,110, 11 genes, copy number 35: LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461.
- chr12:44,008,620–44,010,143, 1 gene, copy number 32: ZNF75BP.
- chr12:45,919,131–49,644,666, 152 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr12:57,693,955–57,978,277, 26 genes, copy number 25: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65.
- chr17:1,995,614–4,733,608, 129 genes, copy number 7 (broad region; genes not listed).
- chr17:12,390,738–12,642,854, 3 genes, copy number 7: AC084167.1, LINC00670, AC068442.1.
- chr17:12,671,862–12,706,135, 1 gene, copy number 7 (within-gene range 3–7): MYOCD-AS1.
- chr17:33,935,437–34,156,000, 1 gene, copy number 7 (within-gene range 3–7): AC004147.4.
- chr17:34,036,681–34,726,170, 20 genes, copy number 7: TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1.
- chr17:43,607,436–44,561,262, 53 genes, copy number 7: Metazoa_SRP, MEOX1, LINC02594, WHSC1L2P, SOST, DUSP3, CFAP97D1, AC003098.1, MPP3, CD300LG, MPP2, AC007993.3, FAM215A, AC007993.1, AC007993.2, LINC01976, PPY, PYY, NAGS, TMEM101, U3, LSM12, G6PC3, HDAC5, AC023855.1, RNU6-131P, HROB, ASB16, ASB16-AS1, TMUB2, ATXN7L3, AC004596.1, UBTF, MIR6782, AC003102.1, SHC1P2, SLC4A1, AC003043.2, RN7SL507P, RUNDC3A-AS1, U3, RNU6-453P, RUNDC3A, SLC25A39, AC003043.1, GRN, FAM171A2, RPL7L1P5, ITGA2B, GPATCH8, RN7SL258P, AC103703.1, FZD2.
- chr17:57,771,946–57,834,749, 1 gene, copy number 7 (within-gene range 5–7): AC015845.2.
- chr17:57,834,781–68,763,882, 355 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr17:77,516,887–80,966,371, 98 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 35. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
